Somatic mutation profile of tumor specimen TARGET-30-PANBCI-01A (aliquot TARGET-30-PANBCI-01A-01W) from TARGET case TARGET-30-PANBCI, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 2.1 years (753 days).
Specimen TARGET-30-PANBCI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6946b6f1-52ed-4f4f-acea-ca938a020c62.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PANBCI-10A (Blood Derived Normal), aliquot TARGET-30-PANBCI-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2cce2ec-7118-497e-a2a0-40313cf004fa

The open-access MAF lists 11 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 9, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3824G>A p.R1275Q | Missense Mutation (SNP) | VAF 26/174 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs113994087, CM085230, COSV66555567, COSV66558183; ClinVar: pathogenic / likely pathogenic /  risk factor; called by muse, varscan2
- ABTB2 | c.1940T>C p.L647P | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV54393337; called by muse, varscan2
- ARHGAP20 | c.2405C>A p.S802Y | Missense Mutation (SNP) | VAF 55/280 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs748951088, COSV52816489; called by muse, mutect2, varscan2
- CAMK1G | c.1313C>A p.T438K | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV50524448; called by muse, mutect2, varscan2
- CD101 | c.145C>T p.Q49* | Nonsense Mutation (SNP) | VAF 58/281 reads (21%) | catalogued as rs1553185140, COSV56719936; called by muse, mutect2, varscan2
- FRAS1 | c.8986G>A p.D2996N | Missense Mutation (SNP) | VAF 180/891 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV53587134; called by muse, mutect2, varscan2
- GAK | c.721G>A p.G241S | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.057); catalogued as rs1349595107, COSV58507784; called by muse, mutect2, varscan2
- GIT1 | c.1511G>A p.R504H | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.511); catalogued as rs889769504, COSV56403521; called by muse, mutect2, varscan2
- IQGAP1 | c.1296G>T p.E432D | Missense Mutation (SNP) | VAF 42/204 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV51589147; called by muse, mutect2, varscan2
- KDM5A | c.3083C>T p.A1028V | Missense Mutation (SNP) | VAF 53/246 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.11); catalogued as rs546854883, COSV66995097; called by muse, mutect2, varscan2
- DSP | c.3303C>T p.Y1101= | Silent (SNP) | VAF 16/130 reads (12%) | catalogued as rs372440854; ClinVar: likely benign / benign / uncertain significance; called by muse, mutect2, varscan2
